Somatic mutation profile of cancer-model specimen HCM-STAN-0777-C25-85A (3D Organoid, passage 7; aliquot HCM-STAN-0777-C25-85A-01D-A88H-36), derived from the primary tumor of HCMI case HCM-STAN-0777-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 68.0 years (24,820 days).
Specimen HCM-STAN-0777-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbbd8cb9-41b0-4ade-935e-51dcd7ba6bb9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-STAN-0777-C25-10A (Blood Derived Normal), aliquot HCM-STAN-0777-C25-10A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c649457-4934-4636-9451-c83286de053c

The open-access MAF lists 83 somatic variants for this specimen: 60 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 19, Frame Shift Ins 4, Nonsense Mutation 3, In Frame Del 2, Intron 2, Splice Site 1, Frame Shift Del 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL2A1 | c.3589G>A p.G1197S | Missense Mutation (SNP) | VAF 111/487 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs121912870, CM910093; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 156/320 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 371/371 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS10 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 208/462 reads (45%) | catalogued as COSV99546265; called by muse, mutect2, varscan2
- ADGRB1 | c.4004G>A p.R1335Q | Missense Mutation (SNP) | VAF 217/751 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as rs753823931; called by muse, mutect2, varscan2
- AFG3L2 | c.1143C>G p.F381L | Missense Mutation (SNP) | VAF 95/202 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52313760, COSV99301591; called by muse, mutect2, varscan2
- BAHCC1 | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 219/891 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs944741353; called by muse, mutect2, varscan2
- BSN | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 203/436 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as rs962864521; called by muse, mutect2, varscan2
- C1QL1 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 172/835 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs761519417, COSV99492764; called by muse, mutect2, varscan2
- CDX1 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 136/458 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV51568430; called by muse, mutect2, varscan2
- COL8A1 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 131/433 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs558799692; called by muse, mutect2, varscan2
- HECW1 | c.2995C>T p.R999C | Missense Mutation (SNP) | VAF 96/444 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760980182, COSV67841998; called by muse, varscan2
- KCNU1 | c.993G>T p.K331N | Missense Mutation (SNP) | VAF 64/118 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV67757825; called by muse, mutect2, varscan2
- KRTAP20-1 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 97/224 reads (43%) | PolyPhen probably damaging (0.997); catalogued as COSV58168977; called by muse, mutect2
- LARS1 | c.2181G>C p.L727F (on ENST00000394434 / NM_020117.11; = p.L700F on NM_016460.3) | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50972193; called by muse, mutect2, varscan2
- LOXL2 | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 246/785 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs760460697; called by muse, mutect2, varscan2
- NOL10 | c.35A>G p.Y12C | Missense Mutation (SNP) | VAF 166/512 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1411969013; called by muse, mutect2, varscan2
- RSPH6A | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 191/342 reads (56%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1448069188; called by muse, mutect2, varscan2
- SLC16A14 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 104/365 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202122599, COSV54619632; called by muse, varscan2
- SLC38A4 | c.995C>T p.T332M | Missense Mutation (SNP) | VAF 102/210 reads (49%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs760817445, COSV56966129; called by muse, varscan2
- SOGA3 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 168/337 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100847014; called by muse, mutect2, varscan2
- TMEM74 | c.215A>G p.Q72R | Missense Mutation (SNP) | VAF 65/267 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV52463842; called by muse, mutect2, varscan2
- AC098582.1 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 88/189 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- CDKN2AIPNL | c.167_183del p.D56Gfs*22 | Frame Shift Del (DEL) | VAF 410/706 reads (58%) | called by mutect2, pindel, varscan2
- CEP83 | c.1397dup p.N466Kfs*2 | Frame Shift Ins (INS) | VAF 22/140 reads (16%) | called by mutect2, varscan2
- CLASRP | c.1451G>T p.R484L | Missense Mutation (SNP) | VAF 222/488 reads (45%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CX3CL1 | c.1060T>C p.C354R | Missense Mutation (SNP) | VAF 221/672 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- DLL1 | c.1918G>C p.D640H | Missense Mutation (SNP) | VAF 267/576 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- DLX4 | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 450/963 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- DOP1B | c.4456C>T p.Q1486* | Nonsense Mutation (SNP) | VAF 178/378 reads (47%) | called by muse, varscan2
- ELF3 | c.386-1G>T p.X129_splice | Splice Site (SNP) | VAF 89/244 reads (36%) | called by muse, mutect2, varscan2
- ELF3 | c.386C>A p.T129N | Missense Mutation (SNP) | VAF 89/244 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM53C | c.818C>A p.S273* | Nonsense Mutation (SNP) | VAF 205/672 reads (31%) | called by muse, mutect2, varscan2
- GAREM2 | c.1429G>C p.V477L | Missense Mutation (SNP) | VAF 184/510 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GPATCH2 | c.947dup p.N316Kfs*8 | Frame Shift Ins (INS) | VAF 68/282 reads (24%) | called by mutect2, pindel, varscan2
- GPNMB | c.170A>C p.K57T | Missense Mutation (SNP) | VAF 78/333 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- KDM6A | c.185_189dup p.E64Ffs*22 | Frame Shift Ins (INS) | VAF 111/114 reads (97%) | called by mutect2, varscan2
- KTN1 | c.2711A>G p.N904S | Missense Mutation (SNP) | VAF 83/178 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- LRP1 | c.4393G>A p.G1465S | Missense Mutation (SNP) | VAF 245/519 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NKX1-2 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 239/739 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- NOP14 | c.901G>C p.D301H | Missense Mutation (SNP) | VAF 81/236 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- NUP62 | c.139C>G p.P47A | Missense Mutation (SNP) | VAF 137/270 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- OR5J2 | c.881A>G p.N294S | Missense Mutation (SNP) | VAF 70/232 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, varscan2
- OR5K2 | c.652T>G p.Y218D | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB10 | c.2011C>A p.L671M | Missense Mutation (SNP) | VAF 609/773 reads (79%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDCD11 | c.2423C>G p.A808G | Missense Mutation (SNP) | VAF 131/396 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- POU2F1 | c.253A>G p.S85G (on ENST00000541643 / NM_001365848.1; = p.S108G on NM_002697.4) | Missense Mutation (SNP) | VAF 19/482 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- PRKG2 | c.242A>C p.K81T | Missense Mutation (SNP) | VAF 15/307 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2
- RAB3GAP1 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAB5B | c.253T>A p.L85I | Missense Mutation (SNP) | VAF 77/394 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RELA | c.155C>A p.T52K | Missense Mutation (SNP) | VAF 62/860 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2
- RGS17 | c.94T>C p.W32R | Missense Mutation (SNP) | VAF 100/185 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- SEC61A2 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- SMO | c.1845_1847del p.S616del | In Frame Del (DEL) | VAF 80/374 reads (21%) | called by pindel, varscan2
- TFDP2 | c.314G>C p.R105T (on ENST00000489671 / NM_001178139.2; = p.R44T on NM_006286.5) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- TRAF3IP3 | c.801_802insC p.V268Rfs*13 | Frame Shift Ins (INS) | VAF 55/273 reads (20%) | called by mutect2, pindel, varscan2
- TRIL | c.1115_1119delinsCC p.R372_W373delinsP | In Frame Del (DEL) | VAF 191/980 reads (19%) | called by pindel, varscan2*
- ULBP2 | c.551A>C p.Y184S | Missense Mutation (SNP) | VAF 180/319 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ZNF234 | c.497A>T p.H166L | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- ZNF727 | c.593G>C p.R198T | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- ADAMTS2 | c.3351C>T p.D1117= | Silent (SNP) | VAF 284/457 reads (62%) | catalogued as rs777279065, COSV104380885; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ARL14EPL | c.54T>C p.H18= | Silent (SNP) | VAF 72/256 reads (28%) | catalogued as COSV59948482; called by muse, mutect2, varscan2
- CSMD1 | c.1089C>T p.S363= | Silent (SNP) | VAF 48/156 reads (31%) | catalogued as rs576618220, COSV68174188; called by muse, mutect2, varscan2
- CUX2 | c.2355C>T p.F785= | Silent (SNP) | VAF 546/1170 reads (47%) | catalogued as COSV55637281; called by muse, varscan2
- DCDC1 | c.4326G>A p.T1442= (on ENST00000597505 / NM_001367979.1; = p.T549= on NM_020869.3) | Silent (SNP) | VAF 60/170 reads (35%) | catalogued as rs761489354, COSV58004359; called by muse, mutect2, varscan2
- DNAH6 | c.8322C>T p.D2774= | Silent (SNP) | VAF 188/293 reads (64%) | catalogued as rs922139524, COSV52861544; called by muse, mutect2, varscan2
- FZD10 | c.1362G>T p.P454= | Silent (SNP) | VAF 154/664 reads (23%) | called by muse, varscan2
- MMP24 | c.1395G>A p.G465= | Silent (SNP) | VAF 196/726 reads (27%) | catalogued as rs1464489370; called by muse, mutect2, varscan2
- PCDHA2 | c.2091C>T p.N697= | Silent (SNP) | VAF 199/671 reads (30%) | catalogued as COSV65367452; called by muse, mutect2, varscan2
- PGAM5 | c.318C>G p.S106= | Silent (SNP) | VAF 247/524 reads (47%) | called by muse, mutect2, varscan2
- PJA2 | c.172C>A p.R58= | Silent (SNP) | VAF 62/264 reads (23%) | called by muse, mutect2
- PLEKHG2 | c.273G>C p.P91= | Silent (SNP) | VAF 254/486 reads (52%) | catalogued as COSV52680558; called by muse, mutect2, varscan2
- PRKCG | c.759C>T p.N253= | Silent (SNP) | VAF 309/635 reads (49%) | catalogued as rs751772455, COSV54726550; called by muse, mutect2, varscan2
- RTL1 | c.2682C>T p.D894= | Silent (SNP) | VAF 158/749 reads (21%) | catalogued as COSV104432787; called by muse, mutect2, varscan2
- SH2D4B | c.702C>T p.D234= | Silent (SNP) | VAF 191/556 reads (34%) | catalogued as rs555708078, COSV57896339; called by muse, mutect2, varscan2
- SLC2A12 | c.534C>T p.G178= | Silent (SNP) | VAF 14/264 reads (5%) | called by muse, mutect2
- UBOX5 | c.99T>C p.D33= | Silent (SNP) | VAF 155/315 reads (49%) | catalogued as rs1568471529; called by muse, mutect2, varscan2
- WHRN | c.2655C>T p.A885= | Silent (SNP) | VAF 189/386 reads (49%) | catalogued as rs775402871, COSV54335188; called by muse, mutect2, varscan2
- ZNF837 | c.1395C>T p.H465= | Silent (SNP) | VAF 347/650 reads (53%) | called by muse, mutect2, varscan2
- CCNYL2 | chr10:42475712 G>A | 5'Flank (SNP) | VAF 40/691 reads (6%) | called by muse, mutect2
- ILRUN | c.*2318A>G | 3'UTR (SNP) | VAF 105/182 reads (58%) | called by muse, mutect2, varscan2
- PGA5 | c.657-83G>A | Intron (SNP) | VAF 174/557 reads (31%) | catalogued as rs1006106706; called by muse, mutect2, varscan2
- WNK1 | c.2140-2230C>A | Intron (SNP) | VAF 102/507 reads (20%) | catalogued as COSV60037015; called by muse, mutect2, varscan2
